Gene-level copy-number profile of tumor specimen TCGA-G4-6625-01A from TCGA case TCGA-G4-6625, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Sigmoid colon; AJCC pathologic stage: Stage IIA; Age at diagnosis: 77.1 years (28,163 days).
Specimen TCGA-G4-6625-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-COAD.24a48ed3-2c84-4410-8ead-177748bac524.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-G4-6625-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 808 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/e517926e-db2c-4ccc-a5b6-8506a6501ff1

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 357; copy number 2: 23,155; copy number 3: 21,668; copy number 4: 8,828; copy number 5: 4,418; copy number 6: 317; copy number 7: 397; copy number 9: 419; copy number 10: 56; copy number 11: 29; copy number 12: 15; copy number 13: 4; copy number 16: 53; copy number 17: 99.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, sample TCGA-G4-6625-01): tumor purity 0.34, ploidy 2.92, whole-genome doublings 1 (call status: legacy_call).

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 3,386 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:14,475–43,045,120, 776 genes, copy number 5 (broad region; genes not listed).
- chr11:130,002,938–135,075,908, 79 genes, copy number 6 (broad region; genes not listed).
- chr13:18,467,172–114,337,626, 1,391 genes, copy number 5–6 (broad region; genes not listed).
- chr20:17,479,085–64,313,132, 1,140 genes, copy number 6–17 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 357. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
